Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A3ZK, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A3ZK-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Report

DOB:
Physician:

Collected:
Received:

Case type: Surgical Case

Accession:

DIAGNOSIS

(A) RIGHT THYROID LOBE AND ISTHMUS:
PAPILLARY THYROID CARCINOMA, CONVENTIONAL TYPE.

Location: Right lobe.

Multifocal: No.

SIZE: 2.5 CM IN GREATEST DIMENSION.

Extrathyroidal extension: Absent.

Lymphovascular invasion: Absent.

Resection margins: Negative.

No tumor present in one lymph node (0/1).

(B) LEFT LOBE OF THYROID:

Thyroid tissue, no tumor present.

(C) PRETRACHEAL LYMPH NODE:

METASTATIC PAPILLARY THYROID CARCINOMA.

(D) TISSUE ANTERIOR TO INNOMINATE ARTERY:

Adipose tissue, no tumor present.

(E) RIGHT PARATRACHEAL AND UPPER MEDIASTINAL LYMPH NODE DISSECTION:

METASTATIC THYROID CARCINOMA IN TWO OF FIFTEEN LYMPH NODES.

Extracapsular extension: Absent.

(F) LYMPH NODES ADJACENT TO RIGHT RECURRENT LARYNGEAL NERVE:

Skeletal muscle, adipose tissue and nerve, no tumor present.

(G) ADDITIONAL UPPER MEDIASTINAL TISSUE:

Fibroconnective tissue, no tumor present.

ICD-0-3

carcinoma, papillary, thyroid 8260/3

Site: thyroid, NOS C73.9

fw

6/17/12

Entire report and diagnosis completed by

GROSS DESCRIPTION

(A) RIGHT THYROID LOBE AND ISTHMUS - A 4.0 x 3.0 x 2.0 cm right lobe of thyroid with isthmus (1.0 x 1.0 x 0.5 cm).

Located in the inferior pole and extending to the superior pole, there is a 2.4 x 2.5 x 1.2 cm, well-circumscribed, golden-brown mass. Representative sections are submitted for frozen section evaluation.

SECTION CODE: A1, A2, representative section for frozen section; A3-A7, mass from superior to inferior (A3 and A4, one slice; A5 and A6, one slice; A7, one slice); A8, isthmus, in toto.

Tissue sent for

*FS/DX: PAPILLARY THYROID CARCINOMA.

[page 2 of 2]
Surgical Pathology Report

DOB
Physician

Collected:
Received:

Pathologist:
Case type: Surgical Case

Accession:

(B) LEFT LOBE OF THYROID - A thyroidectomy specimen with left lobe of thyroid (5.0 x 2.7 x 1.5 cm) and isthmus (1.0 x 0.8 cm). The thyroid is serially sectioned from superior to inferior, there is no lesion present in the specimen. Representative sections submitted.

SECTION CODE: B1, isthmus; B2, upper portion of left thyroid, representative; B3, B4, middle portion of thyroid, left, representative; B5, B6, lower portion of left thyroid, representative.

(C) PRETRACHEAL LYMPH NODE - A tan small lymph node (0.3 x 0.2 x 0.2 cm), bisected and submitted in toto for frozen in one cassette.

*FS/DX: METASTATIC PAPILLARY THYROID CARCINOMA.

(D) TISSUE ANTERIOR TO INNOMINATE ARTERY - An irregular fragment of adipose tissue (0.7 x 0.5 x 0.5 cm). Entirely submitted for frozen section diagnosis in D.

*FS/DX: ADIPOSE TISSUE, NO TUMOR PRESENT.

(E) RIGHT PARATRACHEAL AND UPPER MEDIASTINAL LYMPH NODE DISSECTION - Multiple fragments of fibroadipose tissue (4.0 x 3.0 x 1.0 cm in aggregate). Multiple lymph nodes are identified varying from 0.3 to 0.8 cm in greatest dimension.

SECTION CODE: E1, one possible lymph node trisected; E2, one possible lymph node, trisected; E3, one possible lymph node, bisected; E4, four possible lymph nodes; E5, four possible lymph nodes; E6, one possible lymph node, bisected; E7, one possible lymph node, bisected; E8, four possible lymph nodes; E9, five possible lymph nodes.

(F) LYMPH NODE ADJACENT TO RIGHT RECURRENT LARYNGEAL NERVE - One fragment of soft tan tissue (0.3 x 0.2 x 0.2 cm). Entirely submitted in F.

(G) ADDITIONAL UPPER MEDIASTINAL TISSUE - One fragment of irregular soft tan tissue (0.6 x 0.3 x 0.2 cm). Entirely submitted in G.

CLINICAL HISTORY

Mass of right lobe thyroid.

SNOMED CODES

T-B6000, M-80506

"Some tests reported here may have been developed and performance characteristics determined by
approved by the U.S. Food and Drug Administration."

These tests have not been specifically cleared or

Released by:

Page 2 of 2	
Surgical Pathology Report	
File under: Pathology	

Source: NCI Genomic Data Commons file 6a192a25-bf6c-4c32-a40f-9ccf0a8ad1db (TCGA-EL-A3ZK.1C5F1577-8BE5-470A-8E27-E3CA45200F3A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).